Surgical pathology report (de-identified scan), TCGA case TCGA-5P-A9JW, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5P-A9JW-01A (Primary Tumor).

ICD O-3
Carcinoma, papillary renal cell 8260/3
Site: (L) Kidney NOS C64.9
JUN 6/13/14

Pathology report communicated verbally over the phone.

1.2 cm diameter, papillary, well differentiated Renal Cell Carcinoma (Type II)

Grade: GI/GII

Stage: pT1a, R0

Laterality=(L)

Source: NCI Genomic Data Commons file 619f2cb7-49cc-4195-a39a-dc0f138717de (TCGA-5P-A9JW.2B03AFA2-8EF4-4E67-95A0-0E0B0885F16B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).